MMRF case MMRF_1895 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/963a7a46-f466-46e0-8e33-98986974b436

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 50.8 years (18,560 days); ISS stage: I; Days to last known disease status: 1,005 days (2.8 years); Days to last follow up: 1,005 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 95 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 98 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 122 days; Days to treatment end: 122 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 148 days; Days to treatment end: 148 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 149 days; Days to treatment end: 149 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 287 days; Days to treatment end: 290 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 289 days; Days to treatment end: 289 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 291 days; Days to treatment end: 291 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -11 (ECOG 1): M Protein 2.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.425 mg/dL; Immunoglobulin G 29.9 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 2.43 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 7.6 g/dL; Glucose 5.28 mmol/L.
- Day 81 (ECOG 1): M Protein 0.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.503 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 4.57 mmol/L.
- Day 177 (ECOG 1): M Protein 1.01 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.575 mg/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 1.82 µg/mL; Lactate Dehydrogenase 9.54 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 5.06 mmol/L.
- Day 270 (ECOG 1): M Protein 0.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.983 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.979 mg/dL; Immunoglobulin G 9.46 g/L; Immunoglobulin A 1.13 g/L; Immunoglobulin M 0.54 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 9.49 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Total Protein 6.9 g/dL; Glucose 5.83 mmol/L.
- Day 352 (ECOG 1): M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.621 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.699 mg/dL; Immunoglobulin G 6.3 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 44 g/L; Total Protein 6 g/dL; Glucose 5.28 mmol/L.
- Day 458 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 7.88 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 45 g/L; Total Protein 6.5 g/dL; Glucose 4.95 mmol/L.
- Day 549 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.743 mg/dL; Immunoglobulin G 9.15 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.39 g/L; Beta 2 Microglobulin 1.54 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.43 mmol/L; Albumin 48 g/L; Total Protein 6.9 g/dL; Glucose 5.28 mmol/L.
- Day 640 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 9.98 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.38 mmol/L; Albumin 48 g/L; Total Protein 7.1 g/dL; Glucose 4.73 mmol/L.
- Day 730 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 9.27 g/L; Immunoglobulin A 1.14 g/L; Immunoglobulin M 0.54 g/L; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.38 mmol/L; Albumin 49 g/L; Total Protein 7.4 g/dL; Glucose 5.17 mmol/L.
- Day 823 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.31 mg/dL; Immunoglobulin G 8.93 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 1.4 µg/mL; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 5.17 mmol/L.
- Day 914 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 9.53 g/L; Immunoglobulin A 1.4 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 9.18 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 6.49 mmol/L.
- Day 1,005 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Immunoglobulin G 9.27 g/L; Immunoglobulin A 1.43 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.15 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 5.12 mmol/L.

Other clinical attributes
- Day -11: Weight: 78 kg; Height: 180 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_1895_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -11 days.
- Sample MMRF_1895_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -11 days.
